Surgical pathology report (de-identified scan), TCGA case TCGA-BB-8596, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Johns Hopkins, specimen TCGA-BB-8596-01A (Primary Tumor).

1) LARYNX (LARYNGECTOMY):

SPECIMEN:

Laryngectomy and right hemithyroidectomy

TUMOR SITE:

The tumor involves the right pyriform sinus (hypopharynx) with involvement of the right true vocal cord and right false cord

HISTOLOGIC TYPE:

Squamous cell carcinoma

TUMOR SIZE:

Greatest dimension: 3.0 cm

HISTOLOGIC GRADE:

G3: Poorly differentiated

LYMPH NODES:

None submitted

EXTENT OF INVASION

PRIMARY TUMOR:

pT4a: Tumor invades through thyroid cartilage and focally extends into the thyroid.

REGIONAL LYMPH NODES:

pNx: cannot be assessed

DISTANT METASTASIS:

pMx: Cannot be assessed

MARGINS:

Margins are uninvolved

VENOUS/LYMPHATIC INVASION:

Indeterminate

PERINEURAL INVASION:

Present

Note: The tumor appears to be centered at the right pyriform sinus with involvement of the right true vocal cord and the right false cord. The carcinoma extends into the skeletal muscle and soft tissue adjacent to the right pyriform sinus. The carcinoma extends beyond the thyroid cartilage and focally involves the right thyroid lobe. Tumor cells are also present in the marrow space of the ossified thyroid cartilage. The pathologic stage is pT4aNxMx.

Source: NCI Genomic Data Commons file 9c9eeec5-6126-4a6e-bb0f-b2bf0212ba3e (TCGA-BB-8596.49D3C361-ED56-4568-90FA-450ACE9BF941.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).